Surgical pathology report (de-identified scan), TCGA case TCGA-34-7107, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-7107-01A (Primary Tumor).

FINAL DIAGNOSIS:

**PART 1: LYMPH NODE, RIGHT LEVEL 10, BIOPSY –
ANTHRACOTIC LYMPH NODE FREE OF CARCINOMA.**

**PART 2: LYMPH NODE, RIGHT DEEP LEVEL 4, BIOPSY –
ANTHRACOTIC LYMPH NODE FREE OF CARCINOMA.**

**PART 3: LYMPH NODE, RIGHT LEVEL 4, BIOPSY –
ANTHRACOTIC LYMPH NODE FREE OF CARCINOMA.**

PART 4: SOFT TISSUE, RIGHT POSTERIOR CHEST WALL, EXCISION –
A. PORTION OF LUNG WITH INFLAMMATORY CHANGES, ORGANIZING PNEUMONIA, FIBRIN DEPOSITION AND NECROSIS.
B. NO EVIDENCE OF MALIGNANCY.

PART 5 LYMPH NODE, LEVEL 7, BIOPSY –
A. ANTHRACOTIC LYMPH NODE WITH LIPID GRANULOMAS.
B. NO EVIDENCE OF MALIGNANCY.

PART 6: LUNG, RIGHT, PNEUMONECTOMY –
A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA ASSOCIATED WITH EXTENSIVE NECROSIS, 4.5 CM.
B. NO DEFINITIVE ANGIOLYMPHATIC INVASION IDENTIFIED.
C. EIGHT (8) HILAR LYMPH NODES FREE OF CARCINOMA
D. SURGICAL RESECTION MARGINS FREE OF CARCINOMA.
E. TNM STAGE (AJCC, 7th Edition): pT2a N0.

**PART 7: BONE, RIGHT FIFTH RIB, PARTIAL RESECTION –
PORTION OF BONE, FREE OF CARCINOMA.**

PART 8: PLEURA, RIGHT PARIETAL, RESECTION –
A. PORTION OF LUNG WITH ORGANIZING PNEUMONIA.
B. PLEURA WITH CHRONIC INFLAMMATION AND FIBROSIS.
C. NO EVIDENCE OF MALIGNANCY.

**PART 9 LYMPH NODE, RIGHT LEVEL 10, BIOPSY –
ANTHRACOTIC LYMPH NODE FREE OF CARCINOMA.**

PART 10 LYMPH NODE, RIGHT LEVEL 4, BIOPSY –
A. PORTION OF BENIGN ADIPOSE TISSUE.
B. NO LYMPH NODE TISSUE IDENTIFIED.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Lower Lobe
PROCEDURE:	Pneumonectomy
TUMOR SIZE:	Maximum dimension: 4.5 cm Minor dimension: 4 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive squamous carcinoma, proximal type
HISTOLOGIC GRADE:	G2, Moderately differentiated
MICROSCOPIC "SATELLITES"/METASTASES:	Number of microscopic lesions: 0
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	None identified
ANGIOLYMPHATIC INVASION:	No
TUMOR NECROSIS:	> 50%
SURGICAL MARGIN INVOLVEMENT:	No
INFLAMMATORY(DESMOPLASTIC) REACTION:	Severe
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 10
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 3
UNDERLYING DISEASE(S):	Chronic interstitial pneumonia
T STAGE, PATHOLOGIC:	pT2a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable

Source: NCI Genomic Data Commons file 27068c8e-0492-487b-ade5-18eb02232308 (TCGA-34-7107.E944EC22-44F1-4A7C-A06C-50E0D2D167A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).